Somatic mutation profile of tumor specimen MP2PRT-PASTIP-TBP1-A (aliquot MP2PRT-PASTIP-TBP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASTIP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,512 days).
Specimen MP2PRT-PASTIP-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483712c8-7220-4e65-8334-60ce8abc02c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTIP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTIP-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f06cd189-a4a1-4684-a03c-a6fe95a38b15

The open-access MAF lists 19 somatic variants for this specimen: 7 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 5, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/312 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DGKI | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs761583087, COSV55936470; called by muse, mutect2, varscan2
- SHISA9 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 91/376 reads (24%) | catalogued as rs1459953538, COSV69633132; called by muse, mutect2, varscan2
- SPTLC2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs116822112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRK | c.1747A>T p.T583S | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SHANK1 | c.531+1G>T p.X177_splice | Splice Site (SNP) | VAF 78/343 reads (23%) | called by muse, mutect2, varscan2
- UNC80 | c.8535A>G p.I2845M | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B3GNT6 | c.972C>T p.S324= | Silent (SNP) | VAF 191/802 reads (24%) | catalogued as rs1370158722; called by muse, mutect2
- CRHR1 | c.724C>T p.L242= (on ENST00000398285 / NM_001145146.2; = p.L213= on NM_004382.5) | Silent (SNP) | VAF 137/855 reads (16%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13071C>T p.Y4357= | Silent (SNP) | VAF 100/472 reads (21%) | catalogued as rs763227557; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB2 | c.279G>A p.S93= | Silent (SNP) | VAF 67/435 reads (15%) | catalogued as rs371651342; called by muse, mutect2, varscan2
- GPR39 | c.1023G>A p.P341= | Silent (SNP) | VAF 48/601 reads (8%) | catalogued as rs752733973; called by muse, mutect2
- GRIA3 | c.936C>T p.D312= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs1348055128, COSV52075945; called by muse, mutect2, varscan2
- KCNMB2 | c.369C>T p.S123= | Silent (SNP) | VAF 51/434 reads (12%) | catalogued as rs373338689; called by muse, mutect2, varscan2
- MYO15A | c.837C>T p.Y279= | Silent (SNP) | VAF 101/556 reads (18%) | called by muse, mutect2, varscan2
- RBMXL2 | c.1125C>T p.G375= | Silent (SNP) | VAF 75/378 reads (20%) | catalogued as rs980131375, COSV60978525; called by muse, mutect2, varscan2
- SIGLEC6 | c.831C>T p.D277= | Silent (SNP) | VAF 130/541 reads (24%) | catalogued as rs773742101; called by muse, mutect2, varscan2
- MLXIP | c.1732+63C>T | Intron (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1610C>T | Intron (SNP) | VAF 79/291 reads (27%) | catalogued as rs570172257; called by muse, mutect2, varscan2
